Somatic mutation profile of tumor specimen TCGA-AA-3511-01A (aliquot TCGA-AA-3511-01A-21D-1835-10) from TCGA case TCGA-AA-3511, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 64.1 years (23,407 days).
Specimen TCGA-AA-3511-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c299a2c9-8e09-43f0-acf9-4f2171212af1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3511-11A (Solid Tissue Normal), aliquot TCGA-AA-3511-11A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62d06f7e-de48-43b3-b3fb-a0a1a59c1464

The open-access MAF lists 118 somatic variants for this specimen: 93 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 23, Nonsense Mutation 10, Frame Shift Del 2, Splice Site 2, 5'Flank 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 32/101 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 25/44 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC244197.3 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs199754105, COSV100557913; called by muse, mutect2, varscan2
- ADCY9 | c.2408C>T p.T803I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53577018; called by muse, mutect2, varscan2
- AMER1 | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779325879, COSV57671673; called by muse, mutect2, varscan2
- AP5M1 | c.151T>A p.F51I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as COSV55105671; called by muse, mutect2, varscan2
- APC | c.4010_4011del p.L1337Pfs*4 | Frame Shift Del (DEL) | VAF 34/52 reads (65%) | catalogued as COSV57333336; called by mutect2, pindel, varscan2
- APC | c.6646C>T p.P2216S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99966935; called by muse, mutect2, varscan2
- APMAP | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs989545848, COSV54174663, COSV99468699; called by muse, mutect2, varscan2
- ATCAY | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs756637199, COSV56656965; called by muse, mutect2, varscan2
- BRINP1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs761356301, COSV56296786; called by muse, mutect2, varscan2
- CACNA2D2 | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs779423998, COSV56565044; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARD6 | c.973T>A p.L325I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV54566877; called by muse, mutect2, varscan2
- CARS1 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.207); catalogued as rs757237908, COSV53456071; called by muse, mutect2, varscan2
- CEP162 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.521); catalogued as COSV57620541; called by muse, mutect2, varscan2
- CMYA5 | c.2125G>C p.E709Q | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV71406706; called by muse, mutect2, varscan2
- COPA | c.2636G>T p.G879V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54104269; called by muse, mutect2, varscan2
- CSMD3 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 11/100 reads (11%) | catalogued as COSV99830502; called by muse, mutect2, varscan2
- CTNND2 | c.2303T>A p.L768* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100474735; called by muse, mutect2, varscan2
- CTNND2 | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs201021638, COSV58918848; called by muse, mutect2, varscan2
- CUX1 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1554518649, COSV52903155; called by muse, mutect2, varscan2
- DFFA | c.197A>T p.D66V | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65477713; called by muse, mutect2, varscan2
- DLL4 | c.598T>C p.C200R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51064017, COSV99989557; called by muse, mutect2, varscan2
- DNAH7 | c.5015C>T p.A1672V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377553964, COSV56770004; called by mutect2, varscan2
- DPPA2 | c.235A>G p.K79E | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV101524750; called by muse, mutect2
- ENOX2 | c.833G>A p.R278Q (on ENST00000338144 / NM_001382520.1; = p.R249Q on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs759616146, COSV57650305; called by muse, mutect2, varscan2
- ETV3L | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs1358984433, COSV71901131; called by muse, mutect2, varscan2
- F2R | c.1258T>C p.Y420H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1039562140, COSV59929382; called by muse, mutect2, varscan2
- FPR1 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs186613919; called by muse, mutect2, varscan2
- FREM2 | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs140036522; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMD1 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.063); catalogued as rs558803401, COSV51962821; called by muse, mutect2, varscan2
- FRYL | c.7501A>T p.I2501L | Missense Mutation (SNP) | VAF 91/264 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV51950627; called by muse, mutect2, varscan2
- GRIA4 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as COSV56902994; called by muse, mutect2, varscan2
- GUCY2F | c.2284A>C p.N762H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV54304158; called by muse, mutect2, varscan2
- HCLS1 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs767550556, COSV58857423; called by muse, mutect2, varscan2
- HEATR5A | c.5845G>C p.V1949L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0.028); catalogued as COSV66342112; called by muse, mutect2, varscan2
- HECW1 | c.3103T>G p.F1035V | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV67832219; called by muse, mutect2
- HLA-DRA | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs530789959, COSV66622719; called by muse, mutect2, varscan2
- HNF4A | c.1283-2A>T p.X428_splice | Splice Site (SNP) | VAF 7/62 reads (11%) | catalogued as COSV57384702; called by muse, mutect2, varscan2
- KALRN | c.2833C>G p.H945D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99563329; called by muse, mutect2, varscan2
- KIF24 | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61456026; called by muse, mutect2, varscan2
- LENG1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377602370; called by muse, mutect2, varscan2
- LPAR1 | c.564T>A p.C188* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV62689527; called by muse, mutect2, varscan2
- MAP3K12 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs1565887675, COSV99913132; called by muse, mutect2
- MCCC2 | c.855C>A p.H285Q | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.139); catalogued as COSV60155035; called by muse, mutect2, varscan2
- MORC3 | c.1510_1512del p.P504del | In Frame Del (DEL) | VAF 35/93 reads (38%) | catalogued as rs745791401; called by mutect2, pindel, varscan2
- MTDH | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100292470; called by muse, mutect2, varscan2
- MYLK4 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758227194, COSV51140290; called by muse, mutect2, varscan2
- MYO18B | c.5884C>T p.R1962* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as rs775766182, COSV59137909; called by muse, mutect2, varscan2
- NCAPG | c.2807T>C p.V936A | Missense Mutation (SNP) | VAF 105/287 reads (37%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.003); catalogued as COSV52270920; called by muse, mutect2, varscan2
- NRK | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.589); catalogued as COSV54599088, COSV99686747; called by muse, mutect2, varscan2
- OR10V1 | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100275407; called by mutect2, varscan2
- OR8K5 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as rs147577134, COSV57889485; called by mutect2, varscan2
- OSTM1 | c.920C>G p.S307* | Nonsense Mutation (SNP) | VAF 14/98 reads (14%) | catalogued as COSV51970329; called by muse, mutect2
- OXR1 | c.721A>C p.M241L (on ENST00000442977 / NM_001198532.1; = p.M240L on NM_018002.3) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56330968; called by muse, mutect2, varscan2
- PAX1 | c.989C>A p.A330D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as COSV68272216; called by muse, mutect2, varscan2
- PCDHB15 | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as COSV50874236, COSV99178872; called by muse, mutect2, varscan2
- PDE4B | c.2099G>A p.S700N | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV100303025, COSV104395131; called by muse, mutect2, varscan2
- PEX1 | c.1556G>C p.S519T | Missense Mutation (SNP) | VAF 72/274 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as rs1219374190, COSV50401625; called by muse, mutect2, varscan2
- PHF14 | c.292A>T p.K98* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as COSV68855768; called by muse, mutect2, varscan2
- PLCB3 | c.2872C>T p.R958* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV54189526; called by muse, mutect2, varscan2
- PPP1R9A | c.3167G>A p.R1056Q | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs745926624, COSV56897461; called by muse, mutect2, varscan2
- PTPRU | c.3328G>A p.V1110I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs778440993, COSV60529968; called by muse, mutect2, varscan2
- RAD9A | c.677T>G p.L226R | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57237267; called by muse, mutect2, varscan2
- RALGAPB | c.2230C>G p.L744V | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.969); catalogued as COSV99485022; called by muse, mutect2
- RELA | c.1450G>A p.V484M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100425786; called by muse, mutect2, varscan2
- ROBO2 | c.2574A>C p.Q858H | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59916973; called by muse, mutect2, varscan2
- SCN11A | c.915A>C p.E305D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100181261; called by muse, mutect2, varscan2
- SCNN1G | c.1450C>A p.L484I | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55599625; called by muse, mutect2, varscan2
- SIM1 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99492200; called by muse, mutect2, varscan2
- SLC2A11 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV55392112; called by muse, mutect2, varscan2
- SMC1B | c.1766A>C p.K589T | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV62530701; called by muse, mutect2, varscan2
- SPART | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 79/142 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs778801809, COSV62085567; ClinVar: likely benign; called by muse, mutect2, varscan2
- SRBD1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs1179215149, COSV55400479; called by muse, mutect2, varscan2
- SUSD5 | c.1696G>A p.G566R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs774564062, COSV58878450; called by muse, mutect2, varscan2
- SWT1 | c.2437C>T p.Q813* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as COSV62256173; called by muse, mutect2, varscan2
- TBC1D32 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV51540502, COSV51545982; called by muse, mutect2, varscan2
- TBC1D5 | c.965G>A p.R322K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV53760958; called by muse, mutect2, varscan2
- TCERG1 | c.1048C>G p.Q350E | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as COSV57038470; called by muse, mutect2, varscan2
- TGM2 | c.1074C>A p.D358E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100821566; called by muse, mutect2
- TGM5 | c.1783C>T p.R595C (on ENST00000220420 / NM_201631.4; = p.R513C on NM_004245.4) | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs777999621, COSV55010503; called by muse, mutect2, varscan2
- TKT | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99964948, COSV99965108; called by muse, mutect2, varscan2
- TLE4 | c.476C>G p.A159G | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54634278; called by muse, mutect2, varscan2
- TLR1 | c.965T>G p.I322S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV100458421; called by mutect2, varscan2
- USH2A | c.14542C>T p.R4848W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs757728612, COSV56325434; called by muse, mutect2, varscan2
- WDR24 | c.1886G>A p.R629Q (on ENST00000248142; = p.R499Q on NM_032259.4) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.34); catalogued as rs377491057; called by muse, mutect2, varscan2
- ZBBX | c.1106A>C p.K369T | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV56792394; called by muse, mutect2
- ZNF20 | c.1046G>A p.R349K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.288); catalogued as rs902275502, COSV100502961; called by mutect2, varscan2
- ZNF20 | c.67T>G p.L23V | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100502964; called by muse, mutect2, varscan2
- ZNF587 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100299386; called by muse, mutect2, varscan2
- ZNF614 | c.574G>C p.V192L | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV54546819; called by muse, mutect2, varscan2
- ARHGEF37 | c.976_977del p.D326Pfs*4 | Frame Shift Del (DEL) | VAF 62/101 reads (61%) | called by pindel, varscan2
- TCF7L2 | c.1318+2dup p.X440_splice (on ENST00000355995 / NM_001367943.1; = p.X417_splice on NM_030756.5) | Splice Site (INS) | VAF 22/58 reads (38%) | called by mutect2, pindel, varscan2
- CAND2 | c.96G>A p.S32= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs767466976, COSV55986475, COSV99928688; called by mutect2, varscan2
- CLIP1 | c.3237C>T p.A1079= (on ENST00000620786 / NM_001247997.1; = p.A1068= on NM_002956.2) | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs145339976; called by muse, mutect2
- COL24A1 | c.4527T>A p.T1509= | Silent (SNP) | VAF 13/126 reads (10%) | catalogued as COSV65308226; called by muse, mutect2
- EPN1 | c.1071G>A p.G357= (on ENST00000270460 / NM_001321263.1; = p.G332= on NM_013333.3) | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs549777387, COSV50039140; called by muse, mutect2, varscan2
- GLRB | c.723T>A p.G241= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV52418391; called by muse, mutect2
- GMEB1 | c.405T>C p.H135= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV99603071; called by muse, mutect2, varscan2
- HSPA6 | c.1710C>A p.R570= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV59061419; called by muse, varscan2
- JAK3 | c.1458C>T p.I486= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as rs1297346398, COSV71685638, COSV71687408; called by muse, mutect2, varscan2
- KRTAP19-1 | c.54C>T p.F18= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as rs748857677, COSV66861013; called by muse, mutect2, varscan2
- MUC16 | c.17667T>G p.T5889= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV101199306; called by muse, mutect2, varscan2
- OR2L8 | c.765C>G p.V255= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV61727132; called by muse, mutect2, varscan2
- OR2T1 | c.621G>T p.L207= | Silent (SNP) | VAF 45/129 reads (35%) | catalogued as rs765263333, COSV63541258, COSV63542243; called by muse, mutect2, varscan2
- PAM | c.2664G>T p.R888= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV57214900; called by muse, mutect2
- PDE6B | c.102G>A p.A34= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs142437453; called by muse, mutect2, varscan2
- SEMA3A | c.1518G>A p.T506= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs780861957, COSV99546067; called by mutect2, varscan2
- STEAP2 | c.105G>T p.V35= | Silent (SNP) | VAF 27/160 reads (17%) | catalogued as COSV99840322; called by muse, mutect2, varscan2
- TLN2 | c.5640G>A p.P1880= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs367781225, COSV100168628, COSV100169041; called by muse, mutect2, varscan2
- TMIGD1 | c.198C>G p.L66= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV61028782, COSV61028997; called by muse, mutect2, varscan2
- TNR | c.2415T>C p.I805= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV99688801; called by muse, mutect2, varscan2
- TRPC4 | c.2052A>G p.R684= | Silent (SNP) | VAF 38/365 reads (10%) | catalogued as COSV59004205; called by muse, mutect2, varscan2
- TTN | c.15027C>T p.H5009= (on ENST00000591111; = p.H4082= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs397517482, COSV60136667; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP31 | c.2617C>T p.L873= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV54853578; called by muse, mutect2, varscan2
- VPS4B | c.1212T>A p.L404= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as COSV53069861; called by muse, mutect2, varscan2
- ANKRD13C | chr1:70354981 T>A | 5'Flank (SNP) | VAF 16/59 reads (27%) | catalogued as COSV52032515; called by muse, mutect2, varscan2
- MORF4 | n.532A>G | RNA (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2
